Somatic mutation profile of tumor specimen C3L-01603-02 (aliquot CPT0087030009) from CPTAC case C3L-01603, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 63.6 years (23,226 days).
Specimen C3L-01603-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 05c5018d-5484-428c-a2f9-a63ad577ffb1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01603-31 (Blood Derived Normal), aliquot CPT0087460001; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/19ef7746-f3c9-45df-9bcc-28d8b07f4960

The open-access MAF lists 62 somatic variants for this specimen: 41 protein-altering or splice-affecting, 8 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 8, Intron 6, Frame Shift Ins 2, RNA 2, 5'UTR 2, 3'UTR 2, Nonsense Mutation 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AC127029.3 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 115/491 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs71640273, CM030866; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCY4 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 87/320 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs148797686, COSV99353081; called by muse, mutect2, varscan2
- F8 | c.1315G>A p.G439S | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as CM031983, CM080340; called by muse, mutect2, varscan2
- FCGBP | c.7364C>T p.A2455V | Missense Mutation (SNP) | VAF 90/684 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.372); catalogued as rs775584193; called by muse, varscan2
- GBA2 | c.967C>T p.L323F | Missense Mutation (SNP) | VAF 87/345 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs769905389; called by muse, mutect2, varscan2
- GRAMD1C | c.1538G>C p.R513T | Missense Mutation (SNP) | VAF 81/301 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV63983693; called by muse, mutect2, varscan2
- MIIP | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs759958145; called by muse, mutect2, varscan2
- NCLN | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 53/196 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.027); catalogued as rs888950074; called by muse, mutect2, varscan2
- PCDHB12 | c.1109T>C p.I370T | Missense Mutation (SNP) | VAF 60/253 reads (24%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.353); catalogued as rs1554286790; called by muse, mutect2, varscan2
- PIDD1 | c.2657G>A p.R886H | Missense Mutation (SNP) | VAF 63/271 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.066); catalogued as rs147404421; called by muse, mutect2, varscan2
- RBM8A | c.25G>A p.E9K | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV100355398; called by muse, mutect2
- SLC27A6 | c.903G>T p.K301N | Missense Mutation (SNP) | VAF 49/235 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as COSV52487628; called by muse, mutect2, varscan2
- TJP3 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs140801428; called by muse, mutect2, varscan2
- ZNF491 | c.1231T>C p.Y411H | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.662); catalogued as COSV60058097; called by muse, mutect2, varscan2
- ACHE | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 35/133 reads (26%) | called by muse, mutect2, varscan2
- ADGRG1 | c.472A>C p.T158P | Missense Mutation (SNP) | VAF 28/424 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.361); called by muse, mutect2
- ANGPT4 | c.97_118del p.C33Tfs*48 | Frame Shift Del (DEL) | VAF 41/294 reads (14%) | called by mutect2, pindel
- ANKH | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 65/260 reads (25%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- C11orf53 | c.548C>T p.P183L | Missense Mutation (SNP) | VAF 74/255 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- C20orf27 | c.59G>T p.G20V (on ENST00000379772 / NM_001258429.2; = p.G45V on NM_001039140.3) | Missense Mutation (SNP) | VAF 63/224 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CFAP44 | c.3896C>G p.S1299C | Missense Mutation (SNP) | VAF 46/176 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- CHST1 | c.271G>C p.E91Q | Missense Mutation (SNP) | VAF 52/183 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DUS4L | c.830G>A p.C277Y | Missense Mutation (SNP) | VAF 59/257 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- FASTKD5 | c.290G>A p.R97K | Missense Mutation (SNP) | VAF 73/276 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FBXW5 | c.616C>A p.L206M | Missense Mutation (SNP) | VAF 77/282 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- GLP1R | c.1054T>C p.S352P | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- LAMA3 | c.9458G>T p.G3153V (on ENST00000313654 / NM_198129.4; = p.G1544V on NM_000227.6) | Missense Mutation (SNP) | VAF 40/724 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.238); called by muse, mutect2
- LRRC8B | c.807dup p.V270Cfs*17 | Frame Shift Ins (INS) | VAF 32/173 reads (18%) | called by mutect2, pindel, varscan2
- MEX3A | c.353T>A p.L118H | Missense Mutation (SNP) | VAF 76/287 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- MORC2 | c.853A>C p.K285Q (on ENST00000397641 / NM_001303256.3; = p.K223Q on NM_014941.3) | Missense Mutation (SNP) | VAF 62/274 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- MSI2 | c.511C>A p.H171N | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- OGFR | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 68/531 reads (13%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- PPA1 | c.214G>T p.D72Y | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- SAP30L | c.181A>C p.K61Q | Missense Mutation (SNP) | VAF 66/272 reads (24%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SEC23A | c.2243G>T p.S748I | Missense Mutation (SNP) | VAF 58/213 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- SLC12A7 | c.1268T>C p.L423P | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- TMEM245 | c.2635G>C p.G879R | Missense Mutation (SNP) | VAF 59/269 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- TRAF3IP1 | c.1543_1546dup p.Q516Pfs*5 | Frame Shift Ins (INS) | VAF 30/151 reads (20%) | called by mutect2, pindel, varscan2
- UBE3C | c.2380A>G p.T794A | Missense Mutation (SNP) | VAF 128/408 reads (31%) | SIFT tolerated (0.61); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- UNC5CL | c.472G>C p.G158R | Missense Mutation (SNP) | VAF 83/293 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- WDR61 | c.343T>A p.S115T | Missense Mutation (SNP) | VAF 41/147 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- DNAH11 | c.9240G>T p.L3080= | Silent (SNP) | VAF 45/204 reads (22%) | called by muse, mutect2, varscan2
- EYA4 | c.72T>G p.S24= | Silent (SNP) | VAF 77/319 reads (24%) | called by muse, mutect2, varscan2
- FGL1 | c.540A>G p.E180= | Silent (SNP) | VAF 16/117 reads (14%) | called by muse, mutect2, varscan2
- GLI2 | c.2859C>T p.S953= (on ENST00000361492 / NM_001374353.1; = p.S970= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 64/246 reads (26%) | catalogued as rs1476081450; called by muse, mutect2, varscan2
- JADE1 | c.1311C>A p.A437= | Silent (SNP) | VAF 24/574 reads (4%) | called by muse, mutect2
- MBTPS1 | c.1353G>T p.R451= | Silent (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- SCNN1B | c.726C>T p.G242= | Silent (SNP) | VAF 116/399 reads (29%) | catalogued as rs148125384; called by muse, mutect2, varscan2
- TNC | c.3984C>T p.G1328= | Silent (SNP) | VAF 58/228 reads (25%) | catalogued as rs554908600, COSV60781212; called by muse, mutect2, varscan2
- AL035696.1 | n.291C>A | RNA (SNP) | VAF 73/223 reads (33%) | called by muse, mutect2, varscan2
- C11orf52 | chr11:111929879 T>G | 3'Flank (SNP) | VAF 93/353 reads (26%) | called by muse, mutect2, varscan2
- DYRK4 | c.1321+40G>A | Intron (SNP) | VAF 55/168 reads (33%) | catalogued as rs752395363; called by muse, mutect2, varscan2
- HMOX1 | c.-54C>T | 5'UTR (SNP) | VAF 94/437 reads (22%) | called by muse, mutect2, varscan2
- MLC1 | c.*18C>T | 3'UTR (SNP) | VAF 85/365 reads (23%) | catalogued as rs111797969; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO10 | c.21+19684C>T | Intron (SNP) | VAF 80/306 reads (26%) | called by muse, mutect2, varscan2
- PCDHGB5 | c.2397+48T>A | Intron (SNP) | VAF 25/107 reads (23%) | called by muse, mutect2, varscan2
- RNF103 | c.366+2312T>A | Intron (SNP) | VAF 31/127 reads (24%) | called by muse, mutect2, varscan2
- RPL3 | c.688+103G>A | Intron (SNP) | VAF 94/309 reads (30%) | catalogued as rs377149797; called by muse, mutect2, varscan2
- SNORD115-14 | n.13A>G | RNA (SNP) | VAF 92/331 reads (28%) | called by muse, mutect2, varscan2
- SPNS1 | c.*58G>A | 3'UTR (SNP) | VAF 85/359 reads (24%) | catalogued as rs748746757; called by muse, mutect2, varscan2
- TNNT3 | c.116-50G>A | Intron (SNP) | VAF 19/369 reads (5%) | catalogued as rs777783710, COSV53488726; called by muse, mutect2
- VCP | c.-33C>T | 5'UTR (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
